CCDI case PBCBSA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/53902fdf-1b78-476a-9092-db9309a66339

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (727 days).

Biospecimens (3 samples)
- Sample 0DNRTP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNRTW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNRUT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
